Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5180, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5180-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with 4.5 x 4.1 cm exophytic right solid renal mass.

TCGA-BP-5180

Specimens Submitted:

1: SP: Right renal tumor

2: SP: Small satellite tumor, right kidney

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 4.0 CM. ✓
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. ✓
- DEEP MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. ✓
- 2) KIDNEY, RIGHT "SMALL SATELLITE TUMOR"; EXCISION:
- BENIGN RENAL PARENCHYMA. ✓

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation labeled, "Right renal tumor", and consists of a 7.0 X. 5.5 x.3.0 cm resected portion of kidney with attached fat. The resected margin is inked black. Cut section shows a 4.0 X. 3.0 X. 2.7 cm round, well encapsulated, hemorrhagic orange tumor located 0.2 cm from the resected margin. The remainder of the renal parenchyma is brown tan and unremarkable. A portion is frozen. Representative sections are submitted. A sample of the tumor is given to TPS.

Summary of sections:

FSC -- frozen section control

T-- tumor

U-undesignated

2) The specimen is received in formalin, labeled "Small satellite tumor, right kidney". It consists of an ovoid tan soft tissue measuring 1.0 x 0.9 x 0.2 cm. One of the surfaces is smooth and the opposite seems to be the margin of resection which is inked black. The specimen is trisected to reveal unremarkable cut surface and submitted entirely.

[page 2 of 2]
Summary of Sections:
U - undesignated

Summary of Sections:

Part 1: SP: Right renal tumor [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
6	t	6
1	u	1

Part 2: SP: Small satellite tumor, right kidney [REDACTED]

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: AREA AT STITCH NEGATIVE FOR TUMOR, RENAL CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file e11547f9-318c-4903-9ce5-79940639f1b3 (TCGA-BP-5180.EE501A0B-5443-42BA-A5B5-8694BAA696C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).